National Lung Screening Trial (NLST) participant 111355 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 69 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 60 mA, display field of view 36 cm, reconstruction filter GE Standard.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (1 abnormality; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 20 mm, longest perpendicular diameter 14 mm; margins spiculated (stellate); predominant attenuation mixed; greatest diameter on CT slice 95.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 86, study year T0. Site: middle lobe of lung (ICD-O-3 C34.2). Primary tumour location: right middle lobe. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Grade: poorly differentiated (G3). Tumour size on pathology: 15 mm. AJCC 6th edition staging: stage IA (best stage, from a mixture of clinical and pathologic TNM components); clinical T1 N0 M0 (stage IA); pathologic T1 NX M0. AJCC 7th edition staging: stage IA; clinical T1a N0 M0; pathologic T1a NX M0. Summary stage: localized.
